Somatic mutation profile of tumor specimen TCGA-VQ-A91W-01A (aliquot TCGA-VQ-A91W-01A-11D-A410-08) from TCGA case TCGA-VQ-A91W, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 30.0 years (10,963 days).
Specimen TCGA-VQ-A91W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96cac2fb-0254-4e1d-99ee-a487e44f6a32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91W-10A (Blood Derived Normal), aliquot TCGA-VQ-A91W-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65d27056-3892-4e48-889d-cdc266ed3ed2

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, 3'UTR 2, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 33/118 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen benign (0.221); catalogued as CM126689, COSV55903618; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893815, CM050762, CM159806, COSV55442586, COSV55450248; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APLNR | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.946); catalogued as rs755793037, COSV57241536, COSV99951689; called by muse, mutect2, varscan2
- CROCC | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs200540396, COSV65010877; called by muse, mutect2, varscan2
- DSEL | c.3409T>G p.F1137V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as COSV100026156; called by muse, mutect2, varscan2
- GBA2 | c.1851del p.W617* | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as COSV62306919; called by mutect2, pindel, varscan2
- GJA5 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54784727; called by muse, mutect2, varscan2
- GPR50 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as COSV54441525, COSV99506753; called by muse, mutect2, varscan2
- LAMA3 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs777385606, COSV58079472; called by muse, mutect2, varscan2
- LRP2BP | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs765686066, COSV60749431; called by muse, mutect2, varscan2
- MTNR1A | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV56154968, COSV56156196; called by muse, mutect2, varscan2
- MYH13 | c.3761G>A p.R1254Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs779170976, COSV99355686; called by muse, mutect2, varscan2
- MYL7 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759719930, COSV99790150; called by muse, mutect2
- NRP2 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55930279, COSV99785994; called by muse, mutect2, varscan2
- OR4K1 | c.691A>C p.S231R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV99579486; called by muse, mutect2, varscan2
- OTUB2 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99180238; called by muse, mutect2, varscan2
- PCDHA5 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as COSV65353040; called by muse, mutect2, varscan2
- PLK2 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs779187630, COSV99956328; called by muse, mutect2, varscan2
- PPP1R12A | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.607); catalogued as COSV99700931; called by muse, mutect2, varscan2
- PPP1R3A | c.2539G>T p.E847* | Nonsense Mutation (SNP) | VAF 24/124 reads (19%) | catalogued as COSV52880214; called by muse, mutect2, varscan2
- PREX2 | c.4610C>A p.T1537N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99905405; called by muse, varscan2
- PXDN | c.497A>C p.H166P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99415157; called by muse, mutect2, varscan2
- SORCS3 | c.1406T>G p.I469S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV63801960, COSV63810858; called by muse, mutect2, varscan2
- SPTA1 | c.4329del p.T1444Lfs*10 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as COSV100935717; called by mutect2, pindel, varscan2
- TBX3 | c.627dup p.T210Hfs*17 (on ENST00000257566 / NM_016569.4; = p.T210Hfs*30 on NM_005996.4) | Frame Shift Ins (INS) | VAF 23/115 reads (20%) | catalogued as COSV57472551; called by mutect2, pindel, varscan2
- TNR | c.2859G>T p.M953I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99687880; called by muse, mutect2, varscan2
- TRIM49 | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61670608; called by muse, mutect2, varscan2
- TTN | c.3368C>T p.T1123I (on ENST00000591111; = p.T1077I on NM_003319.4) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | PolyPhen probably damaging (0.925); catalogued as COSV100632839; called by muse, mutect2, varscan2
- ZFP90 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | catalogued as rs765512699, COSV101238838, COSV68050933; called by muse, mutect2, varscan2
- CDH15 | c.2310G>T p.G770= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1380781379, COSV99228931; called by muse, mutect2, varscan2
- DST | c.19674G>A p.Q6558= (on ENST00000361203 / NM_001374722.1; = p.Q4255= on NM_015548.5) | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99760437; called by muse, mutect2, varscan2
- ESR1 | c.1465C>T p.L489= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs767627349, COSV52800091, COSV99241520; called by muse, mutect2, varscan2
- ITGAD | c.1518C>T p.D506= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as rs770920466, COSV101210602; called by muse, mutect2, varscan2
- KCNJ14 | c.357C>T p.A119= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1462065976, COSV100655830; called by muse, mutect2
- MS4A14 | c.906A>G p.Q302= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100280761; called by muse, mutect2, varscan2
- NAGK | c.498A>T p.I166= | Silent (SNP) | VAF 91/273 reads (33%) | catalogued as COSV99730792; called by muse, mutect2, varscan2
- PCDHB15 | c.2088G>A p.S696= | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as rs1554292294, COSV50858875; called by muse, mutect2, varscan2
- SCRN3 | c.693C>A p.A231= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV99767513; called by muse, mutect2, varscan2
- SLC6A15 | c.2149T>C p.L717= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV57023288, COSV99881044; called by muse, mutect2, varscan2
- TBL1Y | c.138G>A p.P46= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs763479323, COSV100667295; called by muse, mutect2, varscan2
- GCNT2 | c.926-35100C>T | Intron (SNP) | VAF 15/84 reads (18%) | catalogued as rs779713259, COSV99399596; called by muse, mutect2, varscan2
- MFSD11 | c.*2C>A | 3'UTR (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100334330; called by muse, mutect2, varscan2
- SLC35A3 | c.*651C>G | 3'UTR (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100924711; called by muse, mutect2, varscan2
